MMRF case MMRF_1513 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1457fce6-b646-4e86-a3a2-38b3081acd0a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.9 years (21,873 days); ISS stage: II; Days to last known disease status: 1,303 days (3.6 years); Days to last follow up: 1,303 days (3.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 889 days (2.4 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 904 days (2.5 years); Days to treatment end: 905 days (2.5 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 906 days (2.5 years); Days to treatment end: 906 days (2.5 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,022 days (2.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 0): M Protein 4.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 263 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.059 mg/dL; Immunoglobulin G 1.76 g/L; Immunoglobulin A 52.6 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 1.52 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 31 g/L; Total Protein 9.4 g/dL; Glucose 4.68 mmol/L; C-Reactive Protein 0.04 mg/dL.
- Day 80 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.672 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.082 mg/dL; Immunoglobulin G 3.01 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 0.3 ×10⁹/L; Platelets 39 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 5.8 g/dL; Glucose 4.79 mmol/L.
- Day 169 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.966 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.143 mg/dL; Immunoglobulin G 3.48 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.34 mmol/L.
- Day 254 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.823 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.655 mg/dL; Immunoglobulin G 6.1 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.29 mmol/L.
- Day 338 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.946 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.629 mg/dL; Immunoglobulin G 8.51 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.46 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.44 mmol/L.
- Day 422 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.765 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 4.57 mmol/L.
- Day 506 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.796 mg/dL; Immunoglobulin G 8.38 g/L; Immunoglobulin A 1.84 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.07 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 590 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.894 mg/dL; Immunoglobulin G 9.29 g/L; Immunoglobulin A 2.07 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 702 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 8.36 g/L; Immunoglobulin A 2.27 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.51 mmol/L.
- Day 786 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.646 mg/dL; Immunoglobulin G 8.68 g/L; Immunoglobulin A 2.9 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.56 mmol/L.
- Day 889 (ECOG 0): M Protein 1.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 56.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 9.57 g/L; Immunoglobulin A 12.7 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 7.1 mmol/L.
- Day 1,003: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.642 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.159 mg/dL; Immunoglobulin G 4.35 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 5.06 mmol/L.
- Day 1,065 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.218 mg/dL; Immunoglobulin G 4.1 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 1,121 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.441 mg/dL; Immunoglobulin G 4.62 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 5.56 mmol/L.
- Day 1,213 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.664 mg/dL; Immunoglobulin G 5.66 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.53 mmol/L; Albumin 47 g/L; Total Protein 7.1 g/dL; Glucose 5.78 mmol/L.
- Day 1,303: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 6.82 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.8 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -19: Weight: 91 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (1 sample)
- Sample MMRF_1513_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
